Somatic mutation profile of tumor specimen TCGA-VS-A8EK-01A (aliquot TCGA-VS-A8EK-01A-12D-A37N-09) from TCGA case TCGA-VS-A8EK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 65.2 years (23,817 days).
Specimen TCGA-VS-A8EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0f13d66-913b-4614-b3e2-95330482cbf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EK-10A (Blood Derived Normal), aliquot TCGA-VS-A8EK-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad8a92f3-27fc-40ce-b1a7-772efe166599

The open-access MAF lists 249 somatic variants for this specimen: 175 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 67, Nonsense Mutation 13, Frame Shift Del 6, Splice Site 4, 3'UTR 3, Intron 2, Splice Region 2, Translation Start Site 1, 5'Flank 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.4204C>T p.Q1402* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1555195442, COSV56443229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.69G>C p.P23= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99788304; called by muse, mutect2, varscan2
- ABI1 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV100697733; called by muse, mutect2, varscan2
- ACSF2 | c.1008C>A p.F336L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99366051; called by muse, mutect2, varscan2
- ACTL7B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101012488; called by muse, mutect2
- AGO4 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100942764; called by muse, mutect2, varscan2
- AGTPBP1 | c.1916C>T p.S639F (on ENST00000357081 / NM_001330701.2; = p.S599F on NM_015239.2) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100429256; called by muse, mutect2, varscan2
- ARHGAP24 | c.1935C>G p.H645Q (on ENST00000395184 / NM_001025616.3; = p.H552Q on NM_031305.3) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.723); catalogued as COSV99981820; called by muse, mutect2, varscan2
- ARL5B | c.26G>A p.W9* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV101040231; called by muse, mutect2, varscan2
- ARSK | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs761684946, COSV101187509; called by muse, mutect2, varscan2
- AXIN2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs761299800, COSV100195907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf78 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs1357226183, COSV100147557; called by muse, mutect2, varscan2
- C1QTNF1 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100189722; called by muse, mutect2, varscan2
- C1orf158 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV55346108, COSV99847200; called by muse, mutect2, varscan2
- CAPN5 | c.967C>T p.R323C (on ENST00000456580; = p.R283C on NM_004055.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372682170; called by muse, mutect2, varscan2
- CASS4 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100824534; called by muse, mutect2, varscan2
- CIZ1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as COSV99476658; called by muse, mutect2, varscan2
- COL24A1 | c.5032C>G p.L1678V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.101); catalogued as COSV100992883, COSV65301569; called by muse, varscan2
- COL6A6 | c.3839T>C p.L1280P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100649807; called by muse, mutect2, varscan2
- CRYBG1 | c.5053G>C p.E1685Q | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100954396; called by muse, mutect2, varscan2
- CUBN | c.6064C>G p.L2022V | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100912060, COSV100912551; called by muse, mutect2, varscan2
- DAPK2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99977064; called by muse, mutect2, varscan2
- DDX59 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100494383; called by muse, mutect2, varscan2
- DHX15 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100391139; called by muse, mutect2, varscan2
- DOP1A | c.2114C>A p.T705K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99380970; called by muse, mutect2, varscan2
- DPYSL2 | c.1231A>C p.I411L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100233593; called by muse, mutect2, varscan2
- DRC7 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV100395368; called by muse, mutect2, varscan2
- EMC1 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV100617423; called by muse, mutect2, varscan2
- EXOSC2 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100964233; called by muse, mutect2, varscan2
- F11 | c.673G>T p.V225F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV99251182; called by muse, mutect2, varscan2
- FAM104B | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV100145955; called by muse, mutect2, varscan2
- FAM222B | c.112C>G p.H38D | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV100368208; called by muse, mutect2, varscan2
- FAM47C | c.590G>C p.C197S | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.254); catalogued as COSV100792276, COSV100792618; called by muse, mutect2
- FBN1 | c.876C>A p.C292* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as CM098622, COSV100354028; called by muse, mutect2, varscan2
- FEZF1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100484400; called by muse, mutect2, varscan2
- FIG4 | c.1866G>A p.M622I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100019130; called by muse, mutect2, varscan2
- FLG | c.4148G>A p.R1383K | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100910512; called by muse, mutect2, varscan2
- FRMD4A | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV99198402; called by muse, mutect2, varscan2
- FURIN | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99184618; called by muse, varscan2
- GALNT12 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100899057; called by muse, mutect2, varscan2
- GATAD2B | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100897801; called by muse, mutect2, varscan2
- GMPR2 | c.1047G>T p.*349Yext*2 (on ENST00000355299 / NM_001351022.2; = p.*367Yext*2 on NM_016576.5) | Nonstop Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99945268; called by muse, mutect2, varscan2
- GPR52 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV52277832, COSV99267759; called by muse, mutect2, varscan2
- GRIA1 | c.2542C>A p.Q848K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV53611550; called by muse, mutect2
- HDHD5 | c.571+2T>G p.X191_splice (on ENST00000336737 / NM_033070.3; = p.X161_splice on NM_017829.5) | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99324467; called by muse, mutect2, varscan2
- HECTD4 | c.9364G>C p.E3122Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs897458784, COSV101106727; called by muse, mutect2, varscan2
- HSPA4 | c.1561-1G>T p.X521_splice | Splice Site (SNP) | VAF 34/40 reads (85%) | catalogued as COSV100507539; called by muse, mutect2, varscan2
- HTATSF1 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99511403; called by muse, mutect2, varscan2
- IDO2 | c.414G>C p.W138C (on ENST00000389060; = p.W151C on NM_194294.2) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478260893, COSV100584536; called by muse, mutect2
- IGKV3-11 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758486991; called by muse, mutect2, varscan2
- IL36A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751426211, COSV52082570; called by muse, mutect2, varscan2
- ILDR2 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99613233; called by muse, mutect2, varscan2
- INTS2 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52153826; called by muse, mutect2, varscan2
- ITGA1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99250691; called by muse, varscan2
- ITGA10 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100994712; called by muse, mutect2, varscan2
- ITGA6 | c.1186C>T p.Q396* (on ENST00000442250; = p.Q357* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99905057; called by muse, mutect2
- ITGA9 | c.2734G>C p.E912Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99291637; called by muse, mutect2, varscan2
- JHY | c.2201C>G p.S734* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99912745; called by muse, mutect2, varscan2
- KAT2A | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV99288007; called by muse, mutect2, varscan2
- KCNA7 | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99671820; called by muse, mutect2, varscan2
- KDM2B | c.2461C>A p.L821I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.157); catalogued as COSV100997188; called by muse, mutect2, varscan2
- KIR2DL3 | c.874-1G>C p.X292_splice | Splice Site (SNP) | VAF 52/252 reads (21%) | catalogued as COSV100667572, COSV60899717; called by muse, varscan2
- KLK7 | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754525282, COSV100304365; called by muse, mutect2
- KPNA1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100724100; called by muse, mutect2, varscan2
- L3MBTL4 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs768516115, COSV99527432; called by muse, mutect2, varscan2
- LEPR | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100756291; called by muse, mutect2, varscan2
- LPP | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs889766019, COSV100446307; called by muse, mutect2, varscan2
- MAGEC1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV99594844; called by muse, mutect2, varscan2
- MAP3K20 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV100168734; called by muse, mutect2, varscan2
- MED23 | c.184T>A p.W62R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100644762; called by muse, mutect2, varscan2
- MELK | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as COSV99974240; called by muse, mutect2, varscan2
- MIA2 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99696618; called by muse, mutect2, varscan2
- MIR9-1HG | n.575-2A>C | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100024031; called by muse, mutect2, varscan2
- MKI67 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100896168; called by muse, mutect2, varscan2
- MR1 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV99294783; called by muse, mutect2, varscan2
- MS4A15 | c.338G>A p.G113E (on ENST00000405633 / NM_001098835.2; = p.G20E on NM_152717.3) | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100558826; called by muse, mutect2
- MS4A15 | c.340G>A p.G114R (on ENST00000405633 / NM_001098835.2; = p.G21R on NM_152717.3) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338676791, COSV100558828; called by muse, mutect2
- MTF1 | c.1628T>A p.V543D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100888571; called by muse, mutect2, varscan2
- MYO1C | c.1870C>T p.R624C (on ENST00000648651 / NM_001080779.2; = p.R589C on NM_033375.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV62998677; called by muse, varscan2
- NMD3 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs777533028, COSV100664604; called by muse, mutect2, varscan2
- NMU | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as COSV99946430; called by muse, varscan2
- NOS1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100500033, COSV57608161; called by muse, mutect2, varscan2
- NOTCH1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99485230; called by muse, varscan2
- NRDE2 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100583274; called by muse, mutect2, varscan2
- NRG1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs146885321, COSV55174404; called by muse, mutect2, varscan2
- NSD3 | c.2075G>C p.R692T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV100388458; called by muse, mutect2, varscan2
- NSUN2 | c.2001T>G p.N667K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99242931; called by muse, mutect2, varscan2
- NTAQ1 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1442817942, COSV99783514; called by muse, mutect2, varscan2
- OR4A5 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV100156961, COSV60524312; called by muse, mutect2, varscan2
- OR5M11 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs544158488, COSV73141926; called by muse, mutect2, varscan2
- OR8S1 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV100043455; called by muse, mutect2, varscan2
- ORC6 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99530797; called by muse, mutect2, varscan2
- PBRM1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99967397; called by muse, mutect2, varscan2
- PITX3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64175089; called by muse, mutect2, varscan2
- PLEKHG4B | c.2290G>A p.E764K (on ENST00000283426; = p.E1120K on NM_052909.5) | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV52044104, COSV99359917; called by muse, mutect2, varscan2
- PLXNA3 | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs782496931, COSV100859805; called by muse, mutect2, varscan2
- PRDM5 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV99309854; called by muse, mutect2, varscan2
- PRKCZ | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs139990959; called by muse, mutect2, varscan2
- PSMD13 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100728724; called by muse, mutect2, varscan2
- PSORS1C1 | c.77T>A p.L26H | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as COSV99455948; called by muse, varscan2
- PTDSS1 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as COSV99749567; called by muse, mutect2, varscan2
- PUS3 | c.614A>G p.D205G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99916794; called by muse, mutect2, varscan2
- RASGRP2 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1424307374, COSV100818154; called by muse, mutect2, varscan2
- RBM18 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101313767; called by muse, mutect2
- RC3H2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as COSV100106287; called by muse, mutect2, varscan2
- RCHY1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as COSV100185721; called by muse, mutect2, varscan2
- RGL2 | c.1373A>G p.D458G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101004714; called by muse, mutect2, varscan2
- RIMKLA | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs751209721, COSV101290550; called by muse, mutect2, varscan2
- RLN2 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100395728; called by muse, mutect2, varscan2
- RTL8A | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100887697; called by muse, mutect2, varscan2
- SACS | c.10021G>C p.D3341H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV101207169, COSV66537311, COSV66540012; called by muse, mutect2, varscan2
- SAFB | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs754213071, COSV52649982; called by muse, mutect2, varscan2
- SCFD1 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99249277, COSV99249305; called by muse, mutect2, varscan2
- SCN1A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV100319333; called by muse, mutect2, varscan2
- SETD3 | c.834C>G p.N278K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074832; called by muse, mutect2
- SHF | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99334224; called by muse, mutect2, varscan2
- SIGLECL1 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV100323821; called by muse, mutect2, varscan2
- SKIV2L | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV100952589; called by muse, mutect2, varscan2
- SLC22A5 | c.1360T>A p.Y454N | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99809616; called by muse, mutect2, varscan2
- SLC35G2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101261968; called by muse, mutect2, varscan2
- SLC39A10 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1156860399, COSV100660495; called by muse, mutect2, varscan2
- SLCO1C1 | c.1914C>T p.F638= | Splice Region (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99858468; called by muse, mutect2, varscan2
- SMC4 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100424377; called by muse, mutect2, varscan2
- SOX5 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100506024; called by muse, mutect2, varscan2
- SPICE1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99870868; called by muse, mutect2, varscan2
- SPICE1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99870872; called by muse, mutect2, varscan2
- STIL | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV99680578; called by muse, mutect2, varscan2
- SYNE2 | c.8482C>T p.Q2828* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100646681; called by muse, mutect2, varscan2
- SYNM | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100152427; called by muse, mutect2, varscan2
- TAB3 | c.1494C>A p.S498R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99915760; called by muse, mutect2, varscan2
- TAF2 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as rs557455884, COSV100978426; called by muse, mutect2, varscan2
- TBC1D4 | c.2239A>G p.K747E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as rs1332011697, COSV100884523; called by muse, mutect2, varscan2
- TENM2 | c.4613C>T p.A1538V (on ENST00000518659 / NM_001122679.2; = p.A1299V on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370446142; called by muse, mutect2, varscan2
- TEX14 | c.4198G>A p.E1400K (on ENST00000240361 / NM_001201457.2; = p.E1354K on NM_031272.5) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53628055; called by muse, mutect2, varscan2
- THSD4 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.094); catalogued as rs770097031, COSV99964506, COSV99965604; called by muse, varscan2
- THSD7A | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs375485239; called by muse, mutect2, varscan2
- TNFSF14 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758345856, COSV99838349; called by muse, mutect2, varscan2
- TRAPPC10 | c.2651C>G p.S884C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759204426, COSV99378176; called by mutect2, varscan2
- TRMT2B | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs759145722, COSV100105163; called by muse, mutect2, varscan2
- TRMT5 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143033104; called by muse, mutect2, varscan2
- TRPM3 | c.2728G>A p.V910I (on ENST00000357533 / NM_001366142.2; = p.V753I on NM_020952.6) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as rs764869085, COSV62592952; called by muse, mutect2, varscan2
- UBE2I | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV100171336; called by muse, mutect2, varscan2
- UBE2M | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as COSV99447931, COSV99448026; called by muse, mutect2, varscan2
- UBTD1 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100080699; called by muse, mutect2, varscan2
- USP53 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99917509; called by muse, mutect2, varscan2
- USP54 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.945); catalogued as COSV100160923; called by muse, mutect2, varscan2
- VWF | c.8389G>A p.E2797K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV54613128, COSV99777990; called by muse, mutect2, varscan2
- WASF3 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as COSV100098097; called by muse, mutect2, varscan2
- WDR64 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV63796716; called by muse, mutect2, varscan2
- WNT8A | c.813G>C p.E271D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100843012; called by muse, mutect2, varscan2
- XKR7 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363981147, COSV101629231; called by muse, mutect2, varscan2
- ZBP1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100473023; called by muse, mutect2, varscan2
- ZCCHC24 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100959288; called by muse, mutect2, varscan2
- ZDBF2 | c.5687G>C p.S1896T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as COSV100984354; called by muse, mutect2
- ZGRF1 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV100005328; called by muse, mutect2, varscan2
- ZNF131 | c.1756G>A p.E586K (on ENST00000509156 / NM_001330707.2; = p.E552K on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV100185144; called by muse, mutect2, varscan2
- ZNF207 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.624); catalogued as COSV100340354; called by muse, mutect2, varscan2
- ZNF441 | c.786T>G p.S262R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.766); catalogued as COSV100777397; called by muse, mutect2, varscan2
- ZNF449 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100202791; called by muse, mutect2, varscan2
- ZNF483 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV58517537; called by muse, mutect2
- ZNF697 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101360029; called by muse, mutect2, varscan2
- ZNF704 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs756788376, COSV100589329; called by muse, varscan2
- ZNF804B | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV100301848, COSV60822218; called by muse, mutect2, varscan2
- ABCB10 | c.1666C>G p.H556D | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2
- ECD | c.641_648del p.P214Hfs*26 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- FHOD3 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.055); called by muse, mutect2
- GABRA3 | c.880dup p.Q294Pfs*38 | Frame Shift Ins (INS) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- KMT2C | c.3688_3703del p.D1230Ifs*68 | Frame Shift Del (DEL) | VAF 68/118 reads (58%) | called by mutect2, pindel, varscan2
- LACTB2 | c.862_863del p.*289Vfs*4 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- MAP1A | c.2064_2071del p.L689Nfs*21 | Frame Shift Del (DEL) | VAF 13/21 reads (62%) | called by mutect2, varscan2
- MRC1 | c.3254C>G p.P1085R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO19 | c.2819C>G p.P940R (on ENST00000614623 / NM_001163735.1; = p.P740R on NM_025109.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF126 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, mutect2
- SAYSD1 | c.381_403del p.L128Rfs*7 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- UBR4 | c.4237del p.A1413Qfs*16 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ACAA2 | c.498G>A p.E166= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99551704; called by muse, mutect2, varscan2
- ADAMTS12 | c.2112G>A p.V704= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs764284846, COSV100710287, COSV100711764; called by muse, varscan2
- ANGPT1 | c.510C>A p.T170= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV52439997, COSV52446942; called by muse, mutect2
- ARMC5 | c.1077C>T p.A359= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99192322; called by muse, mutect2, varscan2
- ASCL4 | c.99G>T p.R33= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100661147; called by muse, mutect2, varscan2
- ATG4C | c.1017C>T p.D339= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100507846; called by muse, mutect2, varscan2
- ATP1A4 | c.3042C>T p.L1014= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100927236; called by muse, mutect2, varscan2
- BRPF3 | c.2931G>A p.R977= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs960362653; called by muse, mutect2
- CCDC88C | c.3084G>A p.A1028= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs769185494, COSV101105118; called by muse, mutect2, varscan2
- CPLANE1 | c.9012T>A p.P3004= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV99949654; called by muse, mutect2, varscan2
- CSF1 | c.615C>T p.V205= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60032639; called by muse, mutect2, varscan2
- CSF2RB | c.1101C>T p.H367= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs373186223; called by muse, mutect2, varscan2
- CTSV | c.144G>A p.R48= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99414304; called by muse, mutect2, varscan2
- CYP3A7 | c.66C>G p.L22= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100312552; called by muse, mutect2, varscan2
- DCAF12L2 | c.264G>A p.T88= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs762926253, COSV100758876, COSV63582878; called by muse, mutect2, varscan2
- DNAH10 | c.12486C>T p.I4162= (on ENST00000409039; = p.I4101= on NM_207437.3) | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101291975, COSV69001351; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2460C>T p.F820= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs375893153; called by muse, mutect2, varscan2
- FLT3 | c.2538C>A p.G846= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV54073769, COSV99607381; called by muse, mutect2, varscan2
- FN1 | c.4242C>G p.T1414= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100115984; called by muse, mutect2, varscan2
- FZD5 | c.681C>T p.F227= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV99776215; called by muse, mutect2, varscan2
- H4C12 | c.102C>T p.A34= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs768673900, COSV100694741; called by muse, mutect2, varscan2
- HEATR1 | c.342G>A p.L114= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs1190648937, COSV100857186; called by muse, mutect2, varscan2
- HGH1 | c.687C>T p.F229= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs1363041082; called by muse, varscan2
- IFT22 | c.231G>C p.L77= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100189996; called by muse, mutect2, varscan2
- IGLV2-14 | c.192C>A p.A64= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs934854489; called by muse, mutect2
- JADE3 | c.1872A>G p.R624= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1556373935, COSV99509538; called by muse, mutect2, varscan2
- KDM2B | c.2460G>A p.S820= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100997189; called by muse, mutect2, varscan2
- KDM6B | c.162C>T p.P54= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs777295095, COSV99640740; called by muse, mutect2, varscan2
- KIR3DL2 | c.882C>T p.F294= | Silent (SNP) | VAF 39/186 reads (21%) | catalogued as rs1415594288; called by muse, mutect2, varscan2
- LRRK2 | c.6711C>A p.T2237= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100109254; called by muse, mutect2
- LZTS1 | c.1035C>G p.L345= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99742671; called by muse, mutect2, varscan2
- LZTS1 | c.831C>G p.L277= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1262049806, COSV99742674; called by muse, mutect2, varscan2
- MAP4K4 | c.780G>A p.K260= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100153452; called by muse, mutect2, varscan2
- MARK4 | c.441C>T p.L147= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs565217769, COSV53461352; called by muse, mutect2, varscan2
- MORN1 | c.195G>A p.A65= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1393492545, COSV58100158; called by muse, mutect2, varscan2
- MTERF1 | c.1119G>A p.L373= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100699536; called by muse, mutect2, varscan2
- MUC16 | c.21630A>T p.S7210= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101198109; called by muse, mutect2, varscan2
- MYH3 | c.3813G>A p.L1271= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs778982808, COSV99877722; called by muse, mutect2, varscan2
- NDUFS1 | c.150C>G p.L50= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99260381; called by muse, mutect2, varscan2
- NRDC | c.1506C>T p.I502= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100703082, COSV61404948; called by muse, mutect2, varscan2
- ORC4 | c.198C>T p.I66= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs1048897403, COSV99931982; called by muse, mutect2, varscan2
- PCDHB12 | c.30G>A p.Q10= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99506730; called by muse, mutect2, varscan2
- PDE8B | c.1134G>A p.K378= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99366153; called by muse, mutect2, varscan2
- PLXNA1 | c.4107G>A p.L1369= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99302301; called by muse, varscan2
- PNMA8A | c.924G>A p.A308= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs112515812, COSV58136030; called by muse, mutect2, varscan2
- PRAMEF12 | c.1272C>T p.L424= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV100743014; called by muse, mutect2, varscan2
- PTPRN2 | c.1401C>T p.A467= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as rs772404937, COSV67046949; called by muse, mutect2, varscan2
- QSOX1 | c.756C>A p.L252= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV62580717; called by muse, mutect2, varscan2
- RAPGEF1 | c.705C>G p.P235= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100940282; called by muse, mutect2, varscan2
- RHD | c.45C>G p.L15= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as COSV100154887; called by muse, mutect2, varscan2
- RORC | c.1275C>T p.L425= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV59092870; called by muse, mutect2, varscan2
- SI | c.1683C>G p.L561= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100014027; called by muse, mutect2, varscan2
- SIN3B | c.888C>T p.I296= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs373826135; called by muse, mutect2, varscan2
- SLC16A4 | c.504G>A p.L168= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100872901; called by muse, mutect2, varscan2
- SPATA20 | c.483C>G p.G161= (on ENST00000356488 / NM_001258372.1; = p.G177= on NM_022827.4) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99135520; called by muse, mutect2, varscan2
- TENM1 | c.5085C>T p.L1695= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as rs1329652381, COSV100949065; called by muse, mutect2, varscan2
- TLR7 | c.378C>T p.L126= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV66124859; called by muse, mutect2, varscan2
- TMEM161A | c.84G>A p.A28= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99365360; called by muse, mutect2
- TTN | c.8544C>A p.V2848= (on ENST00000591111; = p.V2802= on NM_003319.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100594465; called by muse, mutect2, varscan2
- UNC5CL | c.1083C>G p.T361= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs551159599, COSV99770531; called by muse, mutect2, varscan2
- VPS18 | c.2421C>T p.S807= | Silent (SNP) | VAF 31/44 reads (70%) | catalogued as rs143467160; called by muse, mutect2, varscan2
- VWF | c.4797G>A p.Q1599= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99777993; called by muse, mutect2, varscan2
- WDR64 | c.1596G>A p.G532= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100843660, COSV63800308; called by muse, mutect2, varscan2
- ZNF468 | c.19C>T p.L7= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV99700329; called by muse, mutect2
- ZNF641 | c.702A>G p.R234= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs776478240, COSV99973350; called by muse, mutect2, varscan2
- ZNF668 | c.1221G>C p.L407= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100336354; called by muse, mutect2, varscan2
- ZNF687 | c.246C>T p.V82= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100133900; called by muse, mutect2, varscan2
- CDC14B | c.160+622C>T | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as rs776828510; called by muse, mutect2, varscan2
- KDM2B | c.*171G>T | 3'UTR (SNP) | VAF 22/39 reads (56%) | catalogued as COSV100997187; called by muse, mutect2, varscan2
- NPPB | c.*2A>T | 3'UTR (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100916064; called by muse, mutect2, varscan2
- PGM1 | c.247-5760G>C | Intron (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100936518; called by muse, mutect2, varscan2
- TNFRSF18 | c.*157C>T | 3'UTR (SNP) | VAF 16/39 reads (41%) | catalogued as rs771347373, COSV100148810; called by muse, mutect2, varscan2
- Y_RNA | chr7:75516198 del ACATCTTTGAATG | 5'Flank (DEL) | VAF 42/128 reads (33%) | called by mutect2, pindel, varscan2
- ZNF665 | c.-29C>G | 5'UTR (SNP) | VAF 6/57 reads (11%) | catalogued as COSV101127919; called by muse, mutect2, varscan2
